Surgical pathology report (de-identified scan), TCGA case TCGA-BF-AAP8, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-AAP8-01A (Primary Tumor).

Case #

Patient: **Age (years):** **Gender:** Male

Clinical diagnosis: Melanoma

Date of procurement:

Sample:

ICD-O-3
Melanoma, epithelized cell 8771/3
Site: Skin @ hand C44.6
4/22/14

Gross description:

The material presented – skin from right hand, surgical resection

Microscopic description:

Received material is skin patch measured 5.5 cm× 6 cm× 5 cm Grade 3
presented with epitheloid melanoma

Final diagnosis: Epitheloid Melanoma

Confidential

Pw T3s- non glabrous.

Source: NCI Genomic Data Commons file 57df8814-58a7-4f43-9d4a-df2e078b74f9 (TCGA-BF-AAP8.97478FA2-9022-4C07-B5B5-6BAC330BF94F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).